Surgical pathology report (de-identified scan), TCGA case TCGA-BC-A8YO, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site UNC, specimen TCGA-BC-A8YO-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

100-0-3
Carcinoma, Hepatocellular NOS
S170/3
Site Liver 022.0
YD 4/13/14

Diagnosis:

A: Gallbladder, cholecystectomy

- Benign gallbladder with no significant pathologic abnormality
- No carcinoma identified

B: Liver and adherent ascending colon and retroperitoneal soft tissue, segments 5 and 6, partial hepatectomy and en block resection

Histologic tumor type/subtype: hepatocellular carcinoma

Histologic grade: Grade 3 (Edmondson and Steiner)

Number of tumors: 1 primary lesion with multiple subcentimeter satellite lesions

Tumor size: 11 cm

Tumor location: Segments 5 and 6

Tumor necrosis: present (involves approximately 20% of microscopically examined tumor)

Worst tumor differentiation: grade 3 (Edmondson and Steiner)

Vascular invasion: present, macrovascular

Perineural invasion: not identified

Capsular invasion: Present

Margins: uninvolved by carcinoma; tumor is 8 mm from the closest inked retroperitoneal soft tissue margin and 1.7 cm from the hepatic resection margin (colonic and vascular en face margins negative for tumor)

Lymph nodes: 11 benign lymph nodes present within pericolonic adipose tissue (0/11)

Satellite lesions: present (multiple subcentimeter lesions)

Background liver: chronic hepatitis, etiology unknown, grade 1, stage 2 (see comment)

[page 2 of 4]
Other extrahepatic spread: present, tumor focally extends through the capsule/visceral peritoneum to involve fibrous adhesions (no microscopic evidence of tumor involvement within underlying colon and soft tissue)

Additional findings:

- Eleven benign colonic lymph nodes (0/11)

AJCC Pathologic TNM stage: pT4 pNx

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

C: Bowel, ileum, resection

- Benign small bowel with fibrous serosal adhesions, acute serositis, and serosal hemorrhage with hemosiderin laden macrophages
- No carcinoma identified

Comment:

Microscopic examination of non-neoplastic liver reveals fibrotic portal tracts with mild bile ductular proliferation and an associated chronic lymphocytic infiltrate consisting almost entirely of lymphocytes. No prominent plasma cell infiltrate is identified. No piecemeal necrosis is identified. There is mixed macrovesicular and microvesicular steatosis involving less than 5% of the hepatic parenchyma and no features are present to suggest involvement by steatohepatitis.

A trichrome stain highlights areas of periportal fibrosis with no evidence of bridging fibrosis or cirrhosis. A reticulin stain also highlights periportal fibrosis but shows an otherwise normal hepatic plate thickness. A DPAS stain shows no evidence of alpha-1-antitrypsin deficiency (no DPAS positive globules identified within hepatocytes). An iron stain shows a mild increase in hepatic iron (grade 1 of 4). The findings are consistent with chronic hepatitis, grade 1, stage 2. The differential diagnosis includes viral hepatitis and autoimmune hepatitis. Correlation with clinical history and laboratory studies is recommended to determine the etiology of the chronic hepatitis.

Clinical History:

The patient is a -year-old female with a clinical diagnosis of HCC.

[page 3 of 4]
Gross Description:

Specimen A is received with one appropriately labeled container additionally labeled "gallbladder".

Previously opened or disrupted: No

Measurements: 4.6 x 3.1 x 0.9 cm

External surface: Yellow/green, smooth and glistening

Luminal contents: Green viscous fluid

Stones present: No

Mucosa: Green and velvety

Wall thickness: 1 mm

Other comments: No

Block #: A1 - Cystic duct margin and representative section

Tissue remains in formalin.

Specimen B is received in formalin appropriately labeled "segments 5 and 6".

Specimen Type: Segmentectomy and right hemicolectomy

Specimen Weight: 745 grams

Measurement: 12.5 x 11 x 7 cm segment of liver with attached right hemicolectomy consisting of 3 cm of terminal ileum and 14 cm of cecum and ascending colon.

Orientation: Anatomical. The liver resection margin is inked blue.

Capsule: There is a 14.5 cm yellow bulging defect with adherent mesenteric fat and colon. Where the tumor is adherent to the mesentery, the surface margin is inked green. The remainder of the capsule is tan/brown and smooth. Beneath the capsular defect there is an 11 x 9 x 6.5 cm white to tan nodular partially circumscribed mass with multiple adjacent budding nodules.

Mass: Further sectioning reveals a blood vessel that is plugged with tumor thrombus. Additionally, the mass extends through the capsule to within 1.1 cm of the green inked mesenteric margin. Where the mass is adherent to the bowel, it appears to extend to but not grossly invade the capsule. The tumor is 1.7 cm from the blue inked hepatic resection margin, and widely free of the distal margin.

Adjacent liver tissue: Tan/brown and unremarkable.

The colonic mucosa is pink/tan with normal folding.

The appendix is surgically absent.

Major portal vein/ hepatic vein:

Gallbladder: See specimen A.

Block Summary:

B1 - Closest blue inked resection margin, perpendicular

B2 - Proximal colonic margin, en face

[page 4 of 4]
- B3 - Distal colonic margin, en face
- B4 - Tumor in relationship to the capsule and adjacent uninvolved tissue
- B5 - Tumor within a blood vessel
- B6 - Representative sections of multiple adjacent tumor nodules
- B7 - Additional tumor nodule
- B8 - Uninvolved liver away
- B9-B10 - Tumor in relationship to the green soft tissue margin, perpendicular
- B11 - Tumor in relationship to the bowel
- B12 - Tumor in relationship to lateral sidewall muscle
- B13 - Vascular margin with thrombus, en face
- B14-B15 - Multiple colonic lymph nodes

Container C is additionally labeled "ileum." It holds a 6 cm in length x 2.1 cm in diameter segment of small bowel. There is a 2.5 x 1.8 cm area of hemorrhagic adhesions 0.5 cm from the closest mucosal margin. The serosal surface is pink/tan and smooth. Opening reveals pink/tan mucosa with normal folding. Beneath the hemorrhagic adhesions, the cut surface is yellow fat.

Block summary:

- C1-C2 - unoriented mucosal margins, en face
- C3 - hemorrhagic adhesions, en face

Source: NCI Genomic Data Commons file 03035735-a615-4275-812f-c60b51af8173 (TCGA-BC-A8YO.BF3E21AE-D9DC-4011-908A-32C6C1FE10FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).